Somatic mutation profile of tumor specimen MP2PRT-PASRKE-TMP1-A (aliquot MP2PRT-PASRKE-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASRKE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (737 days).
Specimen MP2PRT-PASRKE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6e71012-ca98-4363-8069-ab0895f8eb74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASRKE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASRKE-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77c1d2bf-75f3-42a3-ace6-9998e9bc0daf

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- REXO2 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 310/766 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV56277459; called by muse, mutect2, varscan2
- SEMA7A | c.1519C>T p.R507* | Nonsense Mutation (SNP) | VAF 57/535 reads (11%) | catalogued as rs755390599; called by muse, mutect2, varscan2
- RPS5 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 97/280 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
